Somatic mutation profile of tumor specimen MP2PRT-PARYCT-TMP1-A (aliquot MP2PRT-PARYCT-TMP1-A-1-0-D-A835-36) from MP2PRT case MP2PRT-PARYCT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,679 days).
Specimen MP2PRT-PARYCT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01890287-c4f6-44a4-a0de-4e799adfdc87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARYCT-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARYCT-NM1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8504079-01ab-464b-b237-8a28e43fde9f

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 4, Silent 4, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA1549L | c.5341C>T p.R1781C (on ENST00000321505; = p.R2078C on NM_012194.3) | Missense Mutation (SNP) | VAF 482/1052 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1051016390; called by muse, varscan2
- OR10G8 | c.436A>G p.S146G | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773251050, COSV70908312; called by muse, mutect2, varscan2
- SETD2 | c.7162dup p.T2388Nfs*41 | Frame Shift Ins (INS) | VAF 102/310 reads (33%) | catalogued as rs1323986990; called by pindel, varscan2
- KLHL2 | c.622A>G p.S208G | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PTPRS | c.1566G>T p.Q522H | Missense Mutation (SNP) | VAF 260/604 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, varscan2
- TRAF3IP2 | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 181/446 reads (41%) | called by muse, mutect2, varscan2
- C9orf57 | c.84T>C p.F28= (on ENST00000377024 / NM_001371610.1; = p.F6= on NM_001128618.2) | Silent (SNP) | VAF 127/281 reads (45%) | called by muse, mutect2, varscan2
- CHD7 | c.5859G>A p.A1953= | Silent (SNP) | VAF 231/490 reads (47%) | catalogued as rs587783449, COSV71108441; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- LCN15 | c.48C>T p.P16= | Silent (SNP) | VAF 394/829 reads (48%) | called by muse, mutect2, varscan2
- OR6V1 | c.333C>G p.L111= | Silent (SNP) | VAF 117/710 reads (16%) | called by muse, varscan2
